Somatic mutation profile of tumor specimen TARGET-40-PASRNE-01A (aliquot TARGET-40-PASRNE-01A-01D) from TARGET case TARGET-40-PASRNE, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 3.6 years (1,299 days).
Specimen TARGET-40-PASRNE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63d309a4-5fd4-4a46-848e-e9c0e05596e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASRNE-10A (Blood Derived Normal), aliquot TARGET-40-PASRNE-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8ae8ebe-57fd-4c2b-8584-153b4842e827

The open-access MAF lists 41 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, RNA 4, Intron 4, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2B | c.4888G>A p.D1630N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV55890183; called by muse, mutect2, varscan2
- ATP8A1 | c.2695-8C>T | Splice Region (SNP) | VAF 103/193 reads (53%) | catalogued as rs375459418; called by muse, mutect2, varscan2
- KIAA1549 | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs780665573, COSV99651721; called by muse, mutect2, varscan2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- PLCL2 | c.2918C>T p.T973I (on ENST00000615277 / NM_001144382.2; = p.T847I on NM_015184.5) | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV101196729; called by muse, mutect2
- SLC7A13 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52532467, COSV52536543; called by muse, mutect2, varscan2
- THSD7A | c.1903T>A p.C635S | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70270271; called by muse, mutect2, varscan2
- ABHD2 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ANK1 | c.4036G>T p.A1346S | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP2 | c.2250G>T p.K750N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP2 | c.2251C>A p.Q751K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CRP | c.224A>G p.K75R | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2
- DST | c.17374G>A p.E5792K (on ENST00000361203 / NM_001374722.1; = p.E3489K on NM_015548.5) | Missense Mutation (SNP) | VAF 93/573 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- HELZ2 | c.7031C>A p.A2344E (on ENST00000467148 / NM_001037335.2; = p.A1775E on NM_033405.3) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HHIPL1 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LGR5 | c.740A>T p.D247V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MS4A14 | c.1064T>G p.L355R | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MYH1 | c.2770A>C p.K924Q | Missense Mutation (SNP) | VAF 64/595 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- POU2F2 | c.155T>A p.F52Y | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PRSS16 | c.1394T>A p.L465H | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RNASE2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TNRC6C | c.3191A>C p.N1064T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- USP43 | c.2855C>A p.A952D | Missense Mutation (SNP) | VAF 51/467 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF483 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRF2 | c.807C>T p.V269= (on ENST00000296862 / NM_001368115.2; = p.V201= on NM_153839.7) | Silent (SNP) | VAF 199/878 reads (23%) | catalogued as rs780081928; called by muse, varscan2
- ADGRF2 | c.1020C>T p.I340= (on ENST00000296862 / NM_001368115.2; = p.I272= on NM_153839.7) | Silent (SNP) | VAF 317/1258 reads (25%) | catalogued as COSV57288003; called by muse, varscan2
- ADGRF2 | c.1413C>G p.V471= (on ENST00000296862 / NM_001368115.2; = p.V403= on NM_153839.7) | Silent (SNP) | VAF 244/1030 reads (24%) | called by muse, mutect2, varscan2
- AXL | c.1548G>A p.L516= (on ENST00000301178 / NM_021913.5; = p.L507= on NM_001699.6) | Silent (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- CLASP1 | c.1977C>T p.N659= | Silent (SNP) | VAF 66/193 reads (34%) | called by muse, mutect2, varscan2
- DPPA3 | c.108G>A p.T36= | Silent (SNP) | VAF 68/180 reads (38%) | catalogued as rs766520317, COSV61502743; called by muse, mutect2, varscan2
- TRPM1 | c.186G>A p.Q62= | Silent (SNP) | VAF 44/415 reads (11%) | called by muse, mutect2, varscan2
- AC008740.1 | n.85C>T | RNA (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2
- ARFGAP1 | c.530+67G>A | Intron (SNP) | VAF 20/53 reads (38%) | called by muse, varscan2
- CLCA3P | n.335C>A | RNA (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- DLD | c.582+125C>T | Intron (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- DNAH1 | c.3480+131G>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- ELOB | c.*375del | 3'UTR (DEL) | VAF 37/104 reads (36%) | catalogued as rs771135263; called by mutect2, pindel, varscan2
- ERI2 | c.733-41C>T | Intron (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- MBL1P | n.126T>A | RNA (SNP) | VAF 33/102 reads (32%) | called by muse, mutect2, varscan2
- RNU1-129P | chr1:148009482 T>G | 3'Flank (SNP) | VAF 69/229 reads (30%) | called by muse, mutect2, varscan2
- TPTE2P1 | n.566dup | RNA (INS) | VAF 8/10 reads (80%) | called by mutect2, varscan2
